Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6710, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6710-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 8 x 0 x 10 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Muscularis propria
Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15)
Lymphatic invasion: Present
Venous invasion: Absent
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 6d4e175c-dc4f-43ac-b56d-9a8638679549 (TCGA-BR-6710.D5BA9A64-32A3-4B1D-ADB9-4151678A4321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).